Somatic mutation profile of tumor specimen MP2PRT-PAVJGP-TBP1-A (aliquot MP2PRT-PAVJGP-TBP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVJGP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,487 days).
Specimen MP2PRT-PAVJGP-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 916d734e-7975-447b-a6c2-ff47ec3acebe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVJGP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVJGP-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc0db12c-39e4-491e-9ef6-e549f24b3bd2

The open-access MAF lists 21 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 15, Silent 3, Nonsense Mutation 1, In Frame Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 73/300 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CILP | c.2051C>T p.S684L | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs775992863, COSV56025237; called by muse, mutect2, varscan2
- HOOK1 | c.1447G>A p.G483S | Missense Mutation (SNP) | VAF 65/313 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.61); catalogued as COSV64618562; called by muse, mutect2, varscan2
- MARCHF4 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 110/405 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.828); catalogued as COSV56103180; called by muse, mutect2, varscan2
- PCNX1 | c.3782G>A p.R1261Q | Missense Mutation (SNP) | VAF 50/260 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs144988847, COSV53097743, COSV99455659; called by muse, mutect2, varscan2
- RYR1 | c.9062C>T p.P3021L | Missense Mutation (SNP) | VAF 71/272 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs770765832, CM123713; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN1A | c.2500A>G p.I834V (on ENST00000303395 / NM_001202435.3; = p.I823V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs1004532438; called by muse, mutect2
- SYNE1 | c.11414G>A p.R3805Q (on ENST00000367255 / NM_182961.4; = p.R3790Q on NM_033071.3) | Missense Mutation (SNP) | VAF 88/394 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754270893, COSV54921171, COSV55010734; called by muse, varscan2
- ZMIZ1 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 98/546 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.858); catalogued as COSV57899767; called by muse, mutect2, varscan2
- CAMTA1 | c.2944C>T p.R982* | Nonsense Mutation (SNP) | VAF 74/261 reads (28%) | called by muse, mutect2, varscan2
- CTTNBP2 | c.1318G>A p.G440S | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- DST | c.21668G>A p.R7223H (on ENST00000361203 / NM_001374722.1; = p.R4920H on NM_015548.5) | Missense Mutation (SNP) | VAF 89/375 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406857 ATTATACTACCCCATTCACA>TCCC | Missense Mutation (DEL) | VAF 67/213 reads (31%) | called by pindel, varscan2*
- IGKV2D-24 | chr2:90005629 TCACACAGTG>GGTGGA | Missense Mutation (DEL) | VAF 31/157 reads (20%) | called by pindel, varscan2*
- PEX6 | c.2882_2883insCCAAGGCAC p.S961_V962insQGT | In Frame Ins (INS) | VAF 107/581 reads (18%) | called by mutect2, pindel*
- PPARGC1B | c.922A>T p.T308S | Missense Mutation (SNP) | VAF 122/389 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBMXL3 | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 339/715 reads (47%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SMCR8 | c.53_59del p.E18Vfs*54 | Frame Shift Del (DEL) | VAF 51/367 reads (14%) | called by mutect2, pindel, varscan2
- RAX | c.255G>A p.P85= | Silent (SNP) | VAF 122/576 reads (21%) | called by muse, mutect2, varscan2
- RHBG | c.1317C>A p.G439= | Silent (SNP) | VAF 96/291 reads (33%) | called by muse, mutect2, varscan2
- SOX8 | c.552C>T p.S184= | Silent (SNP) | VAF 116/424 reads (27%) | catalogued as rs758823848; called by muse, mutect2, varscan2
